CPTAC case C3N-01411 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e82a4187-ccdc-4934-a4dd-86730c0b6a26

Demographics
Sex at birth: male; Race: asian; Year of birth: 1953; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 64.2 years (23,433 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 445 days (1.2 years); Progression or recurrence: yes; Days to recurrence: 424 days (1.2 years); Days to last follow up: 445 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 7; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 445 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 424 days (1.2 years); Karnofsky performance status: 70; ECOG performance status: 3.
- Days to follow up: 445 days (1.2 years); Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 3.

Other clinical attributes
- Weight: 48 kg; Height: 170 cm; BMI: 16.61.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (14 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-01411-01, C3N-01411-02 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-01411-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 260 mg.
- Sample C3N-01411-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 3 days; Initial weight: 260 mg; Time between clamping and freezing: 19 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01411-24: Section location: Right lung; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3N-01411-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 3 days; Initial weight: 200 mg; Time between clamping and freezing: 20 minutes; Time between excision and freezing: 5 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01411-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Samples C3N-01411-31, C3N-01411-32, C3N-01411-72, C3N-01411-73, C3N-01411-74, C3N-01411-75, C3N-01411-76 (7 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01411-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 3 days; Method of sample procurement: Blood Draw.
